Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A6TG, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A6TG-01A (Primary Tumor).

[page 1 of 4]
Sample #
Gender: Male
DOB:
Race: White
Report Date:

ICD-O-3
Carcinoma, urothelial NOS
Site: ^{CSCF} lateral wall of bladder
path 8/20/13 C67.2
overlapping lesion of bladder C67.8
JW 7/22/13

Pathology Report:

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. Distal right ureter; excision:

- Portion of ureter with urothelial carcinoma in situ.

B. Right pelvic lymph nodes; dissection:

- One of four lymph nodes with metastatic urothelial carcinoma (1/4).
- Largest lymph nodal tumor focus measures 3 mm, with extranodal extension.

C. Left pelvic lymph nodes; dissection:

- Two of ten lymph nodes with metastatic urothelial carcinoma (2/10).
- Largest lymph nodal tumor focus measures 3 mm, with extranodal extension.

D. Urinary bladder, prostate, vas deferens; cystoprostatectomy:

- Bladder with high grade urothelial carcinoma, invading thru the muscularis propria and into the perivesical soft tissue, see pathologic parameters.
- Urothelial carcinoma in situ.
- Prostate with prostatic adenocarcinoma, see pathologic parameters.

E. Right distal ureter, "true margin"; excision:

- Ureter, free of tumor.

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Invasive urothelial carcinoma.
2. Grade of tumor: High grade.
3. Depth of invasion: Extravesicular soft tissue (microscopic).
4. Tumor distribution: Multifocal, invasive carcinoma at dome, right lateral wall and posterior wall; in-situ carcinoma at anterior, posterior and lateral wall.
5. Ureteral margins: Negative for tumor.

[page 2 of 4]
6. Distal urethral margin: Negative for tumor.
7. Soft tissue margin or serosa: Negative for tumor.
8. Lymph nodes: Positive for metastatic urothelial carcinoma (3/14).
9. pTNM: pT3a,N2,MX.

Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

Radical Prostatectomy Pathologic Parameters

1. Gleason Score: 3+3=6.
2. Perineural Invasion: Absent.
3. Tumor Location: Peripheral zone - right and left.
4. Tumor Volume Estimate: 5%.
5. High-grade P.I.N.: Multifocal.
6. Seminal Vesicles: Negative for tumor.
7. Extraprostatic Extension: Absent.
8. Peripheral Margin: Negative for tumor.
9. Distal (apical) Margin: Negative for tumor.
10. Proximal (basilar) Margin: Negative for tumor.
11. Regional Lymph Nodes (right and left): Negative for prostate carcinoma (0/14).
12. pTNM: pT2c,N0,MX.

Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging system for prostatectomy of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [] M.D.
Electronically Signed Out by [], MD

Clinical History:

Patient is a year-old male with bladder cancer undergoing cystectomy.

Specimens Received:

- A: Distal right ureter
- B: Right pelvic lymph nodes
- C: Left pelvic lymph nodes
- D: Bladder, prostate, vas deferens
- E: Right distal ureter with stitch on none margin side

[page 3 of 4]
Gross Description:

The specimens are received in five containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "distal right ureter". Received fresh and placed in formalin is an unoriented 1.4 cm long segment of ureter with attached adipose up to 1.5 cm in thickness. The specimen is serially resection and the ureter is entirely submitted as A1.

B. The second container is additionally identified as, "right pelvic lymph node". Received fresh and placed in formalin is a 6.5 x 5.5 x 3.5 cm aggregate of lobulated yellow fibrofatty tissue. The specimen is dissected for lymph nodes to reveal multiple apparent lymph nodes ranging from 0.5-3.5 cm in greatest dimension. All apparent lymph nodes are submitted as follows:

B1-2: 2 lymph nodes in each cassette

B3-4: One lymph node, sectioned

B5-6: One lymph node, sectioned

C. The third container is additionally identified as, "left lymph node dissection". Received fresh and placed in formalin is a 0.5 x 6.5 x 2.5 cm aggregate of lobulated yellow fibrofatty tissue. The specimen is dissected for lymph nodes to reveal multiple apparent lymph nodes ranging from 0.3-2.5 cm in greatest dimension. All apparent lymph nodes are submitted as follows:

C1: 4 lymph nodes

C2: 2 lymph nodes

C3: One lymph node, bisected

C4-5: One lymph node, bisected

C6-7: One lymph node, sectioned

C8-10: One lymph node, sectioned

D. The fourth container is additionally identified as, "bladder, prostate, vas deferens". Received fresh and placed in formalin is an 11.4 x 8.4 x 4.5 cm cystoprostatectomy specimen with attached mesenteric fat. The bladder measures 8.4 x 7.0 x 4.4 cm. The right ureteral stump measures 1.1 cm and the left 0.7 cm, and both demonstrate patent lumina. The prostate measures 4.4 x 4.1 x 1.9 cm. The right seminal vesicle measures 3.2 x 0.9 x 0.4 cm and the right vas deferens 8.8 x 0.4 cm. The left seminal vesicle measures 3.4 x 0.6 x 0.4 cm and the left vas deferens 9.1 x 0.4 cm. The right half of the prostate and bladder is inked blue and the left half is inked black. The prostate is opened anteriorly along the urethra and continued superiorly through the bladder in a Y-shaped incision. The prostate is serially sectioned from apex to base to reveal yellow-tan parenchyma with multiple nodular white discolorations. The bladder demonstrates a 3.6 x 2.9 x 1.3 cm slightly raised indurated mass

[page 4 of 4]
involving the dome and right posterior/lateral wall. Serial sectioning reveals tumor invasion into the muscularis propria to a depth of 1.2 cm, extending to 0.4 cm from the inked adipose tissue (not a surgical dissection margin at this part of bladder). The remainder of the mucosa is tan-brown, edematous, and glistening with a uniform 1.4 cm wall thickness. The bilateral ureteral orifices are identified and probe patent. Gross photographs are taken. Representative sections are submitted as follows:

- D1: Distal urethral margin
- D2: Right ureteral margin
- D3: Left ureteral margin
- D4: Prostatic apical margin
- D5-9: Right half of the prostate
- D10-13: Left half of the prostate (65% of the prostate submitted)
- D14: Seminal vesicles and vasa deferentia
- D15-19: Representative sections of the tumor with deepest invasion, all full-thickness sections
- D20: Uninvolved anterior wall
- D21: Uninvolved posterior wall
- D22: Uninvolved left wall
- D 23: Uninvolved trigone

E. The fifth container is additionally identified as, "right distal ureter with stitch on non-margin". Received fresh and placed in formalin is a 2.5 cm long segment of ureter with attached adipose tissue. A stitch is present at one end designating the non-margin site. The specimen is serially sectioned and the margin is submitted as E1.

Local/Synchronous Primary Noted	Prostate	✓

Source: NCI Genomic Data Commons file fb10c908-4714-4d4c-8eab-e182d7cf5e61 (TCGA-FD-A6TG.0F4A353C-3292-4C6C-85AC-A621109D3F24.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).